Somatic mutation profile of tumor specimen TCGA-DD-AAVP-01A (aliquot TCGA-DD-AAVP-01A-11D-A40R-10) from TCGA case TCGA-DD-AAVP, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 48.8 years (17,833 days).
Specimen TCGA-DD-AAVP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74d147ea-547f-48b7-a919-0deb63cfaba6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAVP-10A (Blood Derived Normal), aliquot TCGA-DD-AAVP-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/709ce5de-c3e4-4523-b12a-00e49c03ed58

The open-access MAF lists 85 somatic variants for this specimen: 64 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 53, Silent 21, Splice Site 4, Nonsense Mutation 2, Frame Shift Del 2, In Frame Ins 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.104T>G p.I35S | Missense Mutation (SNP) | VAF 32/91 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62687967, COSV62691314, COSV62693017; called by muse, mutect2, varscan2
- ARFIP2 | c.343T>C p.F115L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (1); PolyPhen probably damaging (0.987); catalogued as COSV99601684; called by muse, mutect2, varscan2
- ARHGAP45 | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs769720722, COSV53124512, COSV53125334; called by muse, mutect2
- C22orf39 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs1476042524, COSV99597548; called by muse, mutect2, varscan2
- C3 | c.3439G>T p.V1147F | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99837272; called by muse, mutect2, varscan2
- CNTN1 | c.2082A>G p.I694M | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100751915; called by muse, mutect2, varscan2
- CRIP3 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as COSV99240589; called by muse, mutect2, varscan2
- CSF3R | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.036); catalogued as COSV100118268; called by muse, mutect2, varscan2
- CUBN | c.1192A>C p.I398L | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100913574; called by muse, mutect2, varscan2
- CUX1 | c.2314G>C p.E772Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as COSV99473171; called by muse, mutect2, varscan2
- DPYSL5 | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.131); catalogued as COSV99982818; called by muse, mutect2, varscan2
- FAM111A | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 42/118 reads (36%) | catalogued as COSV100659460; called by muse, mutect2, varscan2
- FSIP2 | c.17350G>A p.A5784T | Missense Mutation (SNP) | VAF 98/235 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.625); catalogued as rs774274371, COSV58096699; called by muse, mutect2, varscan2
- HCN4 | c.2971C>A p.L991M | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.019); catalogued as COSV56084061; called by muse, mutect2, varscan2
- HDAC2 | c.396G>T p.M132I | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100892763; called by muse, mutect2, varscan2
- HMCN1 | c.9105T>G p.C3035W | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99636011; called by muse, mutect2, varscan2
- IGF1R | c.2326C>A p.P776T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV51317334, COSV99163124; called by muse, mutect2, varscan2
- KCTD15 | c.66G>T p.A22= | Splice Region (SNP) | VAF 56/130 reads (43%) | catalogued as COSV99393384; called by muse, mutect2, varscan2
- KIT | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV55409209, COSV55420906; called by muse, mutect2, varscan2
- KMT2A | c.5839C>G p.L1947V | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV100629910; called by muse, mutect2
- LCAT | c.34A>C p.T12P | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99863313; called by muse, mutect2, varscan2
- LRFN5 | c.1505T>C p.V502A | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as rs768146003, COSV99985509; called by muse, mutect2, varscan2
- LVRN | c.696-1G>T p.X232_splice | Splice Site (SNP) | VAF 128/343 reads (37%) | catalogued as COSV100773692; called by muse, mutect2, varscan2
- MAT1A | c.958T>A p.Y320N | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100944493; called by muse, mutect2, varscan2
- MDFI | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV57821686; called by muse, mutect2, varscan2
- MDFI | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV57823060; called by muse, mutect2, varscan2
- MIPOL1 | c.559T>G p.L187V | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100539624; called by muse, mutect2, varscan2
- MLANA | c.272A>C p.K91T | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.124); catalogued as COSV101199969; called by muse, mutect2, varscan2
- MTRF1L | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 71/189 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100922511; called by muse, mutect2, varscan2
- NBEA | c.881A>G p.H294R | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100084353; called by muse, mutect2, varscan2
- NOTUM | c.751A>T p.K251* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV101293837; called by muse, mutect2, varscan2
- PAG1 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV99597918; called by muse, mutect2, varscan2
- PDIA2 | c.912C>A p.F304L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV99250331; called by muse, mutect2, varscan2
- PLCB3 | c.790T>A p.Y264N | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99657764; called by muse, mutect2, varscan2
- PLEKHM1 | c.2197G>T p.D733Y | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101378881; called by muse, mutect2, varscan2
- PPP6R1 | c.1592G>A p.S531N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101337017; called by muse, mutect2, varscan2
- PROX1 | c.346C>T p.L116F | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV54776555, COSV99800240; called by muse, mutect2, varscan2
- PTCH2 | c.3604A>G p.T1202A | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV100808023; called by muse, mutect2, varscan2
- SAGE1 | c.1190A>T p.E397V | Missense Mutation (SNP) | VAF 167/188 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100187948; called by muse, mutect2, varscan2
- SEL1L3 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.247); catalogued as rs750129330, COSV53545862; called by muse, mutect2, varscan2
- SLC30A3 | c.329T>A p.L110Q | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99273871; called by muse, mutect2, varscan2
- SMAP2 | c.1115C>T p.T372I | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.146); catalogued as COSV101019350; called by muse, mutect2, varscan2
- SMARCA1 | c.800A>G p.K267R | Missense Mutation (SNP) | VAF 393/421 reads (93%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV100946729, COSV104427692; called by muse, mutect2, varscan2
- SPATA16 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100651687; called by muse, mutect2, varscan2
- SPATA16 | c.582G>T p.L194F | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as COSV100651688; called by muse, mutect2, varscan2
- SPEG | c.5308A>C p.N1770H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV100405695; called by muse, mutect2, varscan2
- STAG2 | c.836A>G p.D279G | Missense Mutation (SNP) | VAF 187/609 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as COSV54349752, COSV99495450; called by muse, mutect2, varscan2
- TAPT1 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100461250; called by muse, mutect2, varscan2
- THBS2 | c.3372-2A>C p.X1124_splice | Splice Site (SNP) | VAF 31/81 reads (38%) | catalogued as COSV100828098; called by muse, mutect2, varscan2
- THBS2 | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV100828099; called by muse, mutect2, varscan2
- TNFRSF21 | c.1088T>A p.V363E | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99730262; called by muse, mutect2, varscan2
- TRIM43 | c.196A>G p.T66A | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs555638309, COSV99720142; called by muse, mutect2, varscan2
- VPS39 | c.1693T>A p.F565I (on ENST00000348544 / NM_001301138.2; = p.F554I on NM_015289.5) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.021); catalogued as COSV100529617; called by muse, mutect2, varscan2
- WDFY3 | c.2903C>T p.P968L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99885758; called by muse, mutect2, varscan2
- XG | c.263A>G p.N88S | Missense Mutation (SNP) | VAF 60/68 reads (88%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV101151000; called by muse, mutect2, varscan2
- ZDHHC13 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.699); catalogued as COSV101240096; called by muse, mutect2, varscan2
- ZMIZ1 | c.2354+1G>C p.X785_splice | Splice Site (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100566576; called by muse, mutect2, varscan2
- ZNF335 | c.1624G>T p.A542S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100533407; called by muse, mutect2, varscan2
- ZNF768 | c.921C>A p.H307Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100776359; called by muse, mutect2, varscan2
- ARVCF | c.2388_2391del p.L797Cfs*66 | Frame Shift Del (DEL) | VAF 20/42 reads (48%) | called by pindel, varscan2
- DNAI3 | c.2533-3_2549delinsAGAAAACATATCAGAAGTCA p.X845_splice | Splice Site (ONP) | VAF 8/76 reads (11%) | called by mutect2*, pindel, varscan2*
- HERC4 | c.1322dup p.L441Ffs*4 | Frame Shift Ins (INS) | VAF 149/516 reads (29%) | called by mutect2, pindel, varscan2
- PNKP | c.778_790del p.K260Afs*98 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel
- PODXL | c.69_70insGCGTCG p.S23_P24insAS | In Frame Ins (INS) | VAF 24/68 reads (35%) | called by mutect2, varscan2
- ADGRF1 | c.2271G>T p.V757= | Silent (SNP) | VAF 55/157 reads (35%) | catalogued as COSV99347621; called by muse, mutect2, varscan2
- ATR | c.6396T>C p.Y2132= | Silent (SNP) | VAF 72/182 reads (40%) | catalogued as rs774455552, COSV100638597; called by muse, mutect2, varscan2
- BRINP3 | c.1395C>A p.T465= | Silent (SNP) | VAF 30/136 reads (22%) | catalogued as COSV66542837, COSV66543497; called by muse, mutect2, varscan2
- CDH17 | c.367C>A p.R123= | Silent (SNP) | VAF 51/141 reads (36%) | catalogued as COSV50329695, COSV99218041; called by muse, mutect2, varscan2
- GATA3 | c.846C>T p.Y282= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as rs138698611; called by muse, mutect2, varscan2
- HCN3 | c.192G>T p.V64= | Silent (SNP) | VAF 196/303 reads (65%) | catalogued as COSV100751932; called by muse, mutect2, varscan2
- HCRTR2 | c.1278C>A p.L426= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV100904649, COSV63795806; called by muse, mutect2
- IL16 | c.3564C>G p.P1188= (on ENST00000302987 / NM_172217.5; = p.P487= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100250933; called by muse, mutect2, varscan2
- OBSCN | c.12732C>A p.T4244= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99484471; called by muse, mutect2, varscan2
- OR1J1 | c.462G>T p.A154= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV99403266; called by muse, mutect2, varscan2
- OR8K3 | c.450C>T p.L150= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV100449908; called by muse, mutect2, varscan2
- PLXNA4 | c.624T>G p.S208= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV100327206; called by muse, mutect2, varscan2
- PRSS23 | c.57G>C p.G19= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV99722595; called by muse, mutect2, varscan2
- RECQL4 | c.2352G>A p.R784= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV99468263; called by muse, mutect2, varscan2
- S100A8 | c.60C>G p.S20= | Silent (SNP) | VAF 26/159 reads (16%) | catalogued as COSV100907111; called by muse, mutect2, varscan2
- SCN5A | c.873C>T p.N291= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as rs376515775; ClinVar: likely benign; called by muse, mutect2, varscan2
- SIAH3 | c.222C>T p.H74= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV101248062; called by muse, mutect2, varscan2
- UBA2 | c.429G>A p.G143= | Silent (SNP) | VAF 126/326 reads (39%) | catalogued as COSV99875819; called by muse, mutect2, varscan2
- ZNF114 | c.198A>G p.R66= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV100252167; called by muse, mutect2, varscan2
- ZNF30 | c.1488C>T p.A496= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV100340770; called by muse, mutect2, varscan2
- ZNF560 | c.193T>C p.L65= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100039049; called by muse, mutect2, varscan2
